Somatic mutation profile of tumor specimen TCGA-D3-A5GR-06A (aliquot TCGA-D3-A5GR-06A-11D-A27K-08) from TCGA case TCGA-D3-A5GR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 37.4 years (13,645 days).
Specimen TCGA-D3-A5GR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d410c30-413e-49e4-b96d-d54c84aa169f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A5GR-10A (Blood Derived Normal), aliquot TCGA-D3-A5GR-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/663ae6b8-b760-46f0-8422-375ffd47e65d

The open-access MAF lists 312 somatic variants for this specimen: 203 protein-altering or splice-affecting, 105 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 105, Nonsense Mutation 15, Intron 2, RNA 2, Translation Start Site 2, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA8 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV52194533; called by muse, mutect2, varscan2
- ABCG1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59201021; called by muse, mutect2
- ACKR2 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV56176816; called by muse, mutect2, varscan2
- ACSS3 | c.531G>A p.M177I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54085309, COSV54093705; called by muse, mutect2, varscan2
- ADAM18 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV55843937; called by muse, mutect2, varscan2
- AFF4 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs1259299926, COSV54791367; called by muse, mutect2, varscan2
- AHNAK2 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV60908156; called by muse, mutect2, varscan2
- ANKRD30A | c.3961C>T p.Q1321* (on ENST00000611781; = p.Q1265* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV64604163; called by muse, mutect2, varscan2
- ANKRD54 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV53235653; called by muse, mutect2, varscan2
- ANXA1 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.511); catalogued as COSV57410428; called by muse, mutect2, varscan2
- APCDD1 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); catalogued as COSV62372050; called by muse, mutect2, varscan2
- APEX2 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs1020209385, COSV66623771; called by muse, mutect2, varscan2
- APOB | c.3736C>A p.P1246T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51923815; called by muse, mutect2, varscan2
- ARHGEF11 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59352457; called by muse, mutect2, varscan2
- ARID2 | c.5062G>A p.D1688N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV57596299; called by muse, mutect2, varscan2
- ARX | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV66874788; called by muse, mutect2, varscan2
- ASXL3 | c.3859G>A p.G1287R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as rs1348922129, COSV52457780; called by muse, varscan2
- ATF7IP | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53766469; called by muse, mutect2, varscan2
- ATP10A | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.371); catalogued as rs766890861, COSV63513722; called by muse, mutect2, varscan2
- ATP1A4 | c.2394G>A p.M798I | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV63625497; called by muse, mutect2, varscan2
- ATP6AP1 | c.1338G>A p.M446I | Missense Mutation (SNP) | VAF 82/469 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV100870670, COSV63895257; called by muse, mutect2, varscan2
- ATP7A | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100431270, COSV58442856; called by muse, mutect2, varscan2
- B4GALNT3 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56749848; called by mutect2, varscan2
- BAIAP2 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV58338734; called by muse, mutect2, varscan2
- BAIAP2 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs528172800, COSV58334154; called by muse, mutect2, varscan2
- BIRC6 | c.3053C>T p.T1018I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV101429120; called by muse, mutect2
- BMP2K | c.3164G>A p.R1055K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.031); catalogued as COSV55008554; called by muse, mutect2, varscan2
- BMP6 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV51660751; called by muse, mutect2, varscan2
- BOLL | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV56573187; called by muse, mutect2, varscan2
- BSN | c.11671G>A p.D3891N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs760457608, COSV56512780; called by muse, mutect2, varscan2
- C12orf40 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV61129266; called by muse, mutect2
- C8orf34 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV61371186; called by muse, mutect2, varscan2
- CACNA1B | c.5525C>T p.P1842L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53114313; called by muse, mutect2
- CACNA1C | c.4111T>C p.F1371L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59697651; called by muse, mutect2
- CCDC102B | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV60134843; called by muse, mutect2
- CCDC141 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.108); catalogued as COSV55369150, COSV55371057; called by muse, mutect2, varscan2
- CCDC141 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV55368066; called by muse, mutect2, varscan2
- CCDC69 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.724); catalogued as COSV62599087; called by muse, mutect2, varscan2
- CCSER1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV61408428; called by muse, mutect2
- CDH9 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50252882; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1600C>G p.P534A | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV62572157; called by muse, mutect2, varscan2
- CELSR2 | c.7640C>T p.A2547V | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as COSV54766997; called by muse, mutect2
- CERS4 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV52165223, COSV52169030; called by muse, mutect2, varscan2
- CHGB | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV66759608, COSV66762116; called by muse, mutect2
- CHIT1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.041); catalogued as COSV55145321; called by muse, mutect2
- CLEC14A | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1411100346, COSV60561701; called by muse, mutect2, varscan2
- CNBD2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV62586361; called by muse, mutect2, varscan2
- CNOT6L | c.1576C>T p.P526S (on ENST00000504123 / NM_001286790.2; = p.P521S on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53697207; called by muse, mutect2, varscan2
- COL11A1 | c.3796C>T p.P1266S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as COSV62173347; called by muse, mutect2, varscan2
- COL27A1 | c.5014C>T p.L1672F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs770373136, COSV61921683; called by muse, mutect2, varscan2
- COL4A6 | c.3677G>A p.G1226E | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57859560; called by muse, mutect2, varscan2
- COPS4 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV52313718; called by muse, mutect2, varscan2
- CPS1 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392559810, HM080066, COSV51802375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF2RA | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 120/335 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62623574; called by muse, mutect2, varscan2
- CSF3R | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58963492; called by muse, mutect2, varscan2
- CSMD1 | c.9319G>A p.G3107R (on ENST00000520002; = p.G3106R on NM_033225.6) | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59283197; called by muse, mutect2, varscan2
- CTNNA3 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57717101; called by muse, mutect2, varscan2
- CYLC1 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV61411337; called by muse, mutect2, varscan2
- DDX17 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as COSV53246565, COSV53249303; called by muse, mutect2, varscan2
- DDX31 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.338); catalogued as COSV60134243, COSV60138405; called by muse, mutect2, varscan2
- DDX53 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV60068512; called by muse, mutect2, varscan2
- DEFB129 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV55730947; called by muse, mutect2, varscan2
- DENND2C | c.1958C>T p.S653F (on ENST00000393274 / NM_001256404.2; = p.S596F on NM_198459.4) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV67920085; called by muse, mutect2, varscan2
- DICER1 | c.1026G>C p.R342S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.114); catalogued as COSV58615860; called by muse, mutect2, varscan2
- DMD | c.4612C>T p.P1538S | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs778957669, COSV63735681; called by muse, mutect2, varscan2
- DNAH1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.359); catalogued as COSV70226579; called by muse, mutect2, varscan2
- DNAH5 | c.11164G>A p.G3722S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203293825, COSV54204755; called by muse, mutect2, varscan2
- DNAH9 | c.4732G>A p.D1578N | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs1186330478, COSV52333468; called by muse, mutect2, varscan2
- DOCK2 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV56942744; called by muse, mutect2, varscan2
- DPP4 | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62105112; called by muse, mutect2, varscan2
- DSCAM | c.3014G>A p.W1005* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV68021153, COSV68028943; called by muse, mutect2, varscan2
- DYDC1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs140462481, COSV64730883; called by muse, mutect2, varscan2
- DYSF | c.2408G>C p.R803P | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1110874, COSV50268949; called by muse, mutect2, varscan2
- EBF2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68776105; called by muse, mutect2, varscan2
- ELFN2 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.759); catalogued as COSV68743839; called by muse, mutect2, varscan2
- F8 | c.4600C>T p.P1534S | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV64269877; called by muse, mutect2, varscan2
- FAM234B | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV52192616; called by muse, mutect2, varscan2
- FAM47C | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs781976300, COSV63723770, COSV63725510; called by muse, mutect2, varscan2
- FBXO40 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV57522013; called by muse, mutect2, varscan2
- FGF13 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV59543068; called by muse, mutect2, varscan2
- FGFRL1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768438794, COSV53256371; called by muse, mutect2, varscan2
- FLNA | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs1557177704, COSV61037792; called by muse, mutect2, varscan2
- FSTL5 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60182123; called by muse, mutect2
- G2E3 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs997578937, COSV52838478; called by muse, mutect2, varscan2
- GABBR1 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as rs779705251, COSV63540900; called by muse, mutect2, varscan2
- GOLGB1 | c.3638A>T p.N1213I | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV61461883; called by muse, mutect2
- GPR158 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0.33); catalogued as rs1029059062, COSV66265591; called by muse, mutect2, varscan2
- GPR42 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71994998; called by muse, mutect2, varscan2
- GPR55 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV67407060; called by muse, mutect2, varscan2
- GPRIN2 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782198983, COSV65400320; called by muse, mutect2, varscan2
- GRIA2 | c.1418C>A p.A473D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52382740; called by muse, mutect2, varscan2
- GUCY2F | c.2256G>A p.M752I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV54298599; called by muse, mutect2, varscan2
- GYG1 | c.375C>A p.D125E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56048722; called by muse, mutect2, varscan2
- HTR5A | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV55280587, COSV99840025; called by muse, mutect2, varscan2
- HYDIN | c.6536C>T p.S2179F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1344805203, COSV59249551; called by muse, mutect2, varscan2
- IKZF1 | c.1497C>G p.S499R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100498831; called by muse, mutect2, varscan2
- IKZF1 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100498510, COSV100498833; called by muse, mutect2, varscan2
- INPP5D | c.449C>T p.P150L (on ENST00000445964 / NM_001017915.3; = p.P149L on NM_005541.5) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64035462; called by muse, mutect2, varscan2
- IQCA1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266748472, COSV54496109; called by muse, mutect2, varscan2
- ITGA10 | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV65196073; called by muse, mutect2, varscan2
- KBTBD4 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.972); catalogued as COSV58596709; called by muse, mutect2, varscan2
- KCNA6 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs1423494168, COSV54974060; called by muse, mutect2
- KCNMA1 | c.3652C>T p.R1218W (on ENST00000286628 / NM_001161352.2; = p.R1160W on NM_002247.4) | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs201703516, COSV54228542; called by muse, mutect2, varscan2
- KIAA1217 | c.2656C>T p.H886Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV100286145, COSV56812543; called by muse, mutect2, varscan2
- KIF21B | c.4777A>G p.I1593V (on ENST00000422435 / NM_001252100.2; = p.I1580V on NM_017596.4) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.487); catalogued as COSV59752577; called by muse, mutect2, varscan2
- KLK9 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV51590555; called by muse, mutect2, varscan2
- KSR2 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60366520; called by muse, mutect2, varscan2
- LHCGR | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV54292731, COSV54293079; called by muse, mutect2, varscan2
- LRP2 | c.10057G>A p.G3353R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55541400; called by muse, mutect2, varscan2
- LRRN4 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs1305619043, COSV66644503; called by muse, mutect2, varscan2
- LRRTM4 | c.1331A>G p.Y444C | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs941094225, COSV69139040; called by muse, mutect2
- LYST | c.3555G>A p.K1185= | Splice Region (SNP) | VAF 8/85 reads (9%) | catalogued as COSV67703446; called by muse, mutect2, varscan2
- MAGEB1 | c.992C>A p.T331N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66775214; called by muse, mutect2
- MCTS1 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV64892230, COSV64892763; called by muse, mutect2, varscan2
- MGAM | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 97/171 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV72073666; called by muse, mutect2, varscan2
- MS4A12 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV50014061; called by muse, mutect2, varscan2
- MTUS2 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs745785312, COSV70913639; called by muse, mutect2, varscan2
- MUC4 | c.13070C>T p.S4357F (on ENST00000463781 / NM_018406.7; = p.S121F on NM_004532.6) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV57765906; called by muse, mutect2
- MYBPC1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV62251134; called by muse, mutect2, varscan2
- MYH1 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs202103660, COSV56843856; called by muse, mutect2, varscan2
- MYH2 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs1304716713, COSV55431861; called by muse, mutect2, varscan2
- MYO7A | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.442); catalogued as rs782131913, CM990897, COSV68683511; called by muse, mutect2, varscan2
- NCKIPSD | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53659726; called by muse, mutect2, varscan2
- NEB | c.11632C>T p.R3878C | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs762876022, COSV50806160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP3 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs776897356, COSV60220208; called by muse, mutect2
- NLRP8 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs919708988, COSV52583524; called by muse, mutect2, varscan2
- NOTCH2 | c.6838C>T p.P2280S | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56682236; called by muse, mutect2, varscan2
- NOX4 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as COSV54447059; called by muse, mutect2, varscan2
- NOX5 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV52985072; called by muse, mutect2, varscan2
- NRAP | c.5099A>G p.E1700G (on ENST00000359988 / NM_001322945.2; = p.E1665G on NM_006175.4) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV63488554; called by muse, mutect2, varscan2
- NRK | c.3541C>T p.Q1181* | Nonsense Mutation (SNP) | VAF 54/154 reads (35%) | catalogued as COSV54590069; called by muse, mutect2, varscan2
- OR1I1 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV52917352; called by muse, mutect2, varscan2
- OR1L8 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV59185762; called by muse, mutect2, varscan2
- OR2L2 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV63548343, COSV63548796, COSV63552055; called by muse, mutect2, varscan2
- OR2T11 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV100424666, COSV58184782; called by mutect2, varscan2
- OR4C13 | c.819C>A p.Y273* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV73648630; called by mutect2, varscan2
- OR6C74 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59605767; called by muse, varscan2
- OSMR | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57081173, COSV57085213; called by muse, mutect2, varscan2
- PAGE3 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as rs750239248, COSV66586627; called by muse, mutect2, varscan2
- PAK4 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58943757; called by muse, mutect2, varscan2
- PAPPA | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV60277604, COSV60291325; called by muse, mutect2
- PCDH10 | c.2108G>T p.S703I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.133); catalogued as rs758285629, COSV52087741; called by muse, mutect2, varscan2
- PCDH15 | c.2546G>T p.G849V | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.348); catalogued as COSV57264727; called by muse, mutect2, varscan2
- PCDHA6 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV65341946; called by muse, mutect2, varscan2
- PCED1B | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.114); catalogued as COSV71394888; called by muse, mutect2, varscan2
- PHKA2 | c.3295T>G p.S1099A | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.306); catalogued as COSV66052563, COSV66052949; called by muse, mutect2, varscan2
- PIKFYVE | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 31/121 reads (26%) | catalogued as COSV52237102; called by muse, mutect2, varscan2
- PLAGL2 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV55787442; called by muse, mutect2, varscan2
- PLIN4 | c.458G>A p.G153D (on ENST00000301286; = p.G168D on NM_001367868.2) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV56687100; called by muse, mutect2, varscan2
- PLXNA3 | c.4372G>A p.E1458K | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1569554652, COSV63753137; called by muse, mutect2, varscan2
- PRAG1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV58157457; called by muse, mutect2, varscan2
- PRAMEF14 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs75542004; called by muse, mutect2, varscan2
- PRAMEF6 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 30/540 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as rs1433844426; called by muse, mutect2
- PRDM11 | c.631G>A p.D211N (on ENST00000530656 / NM_001359633.1; = p.D177N on NM_001256695.1) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as COSV55437580; called by muse, mutect2, varscan2
- PRKX | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99468748; called by muse, varscan2
- RAB40AL | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.943); catalogued as COSV99505320; called by muse, mutect2, varscan2
- RAB5A | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56083562; called by muse, mutect2, varscan2
- RNASE13 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV58794226; called by muse, mutect2, varscan2
- ROS1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100877532, COSV63851408; called by muse, mutect2, varscan2
- SCMH1 | c.1547C>T p.P516L (on ENST00000326197 / NM_001031694.2; = p.P469L on NM_012236.4) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100402276; called by muse, mutect2, varscan2
- SCMH1 | c.1546C>T p.P516S (on ENST00000326197 / NM_001031694.2; = p.P469S on NM_012236.4) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1448055386, COSV100402279; called by muse, mutect2, varscan2
- SHCBP1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV100317444, COSV57646375; called by muse, mutect2
- SI | c.1768A>G p.T590A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV52266548; called by muse, mutect2, varscan2
- SLC2A2 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as COSV58584616; called by muse, mutect2, varscan2
- SLC33A1 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100848350, COSV63947261; called by muse, mutect2, varscan2
- SLC9A9 | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV100342790, COSV57218707; called by muse, mutect2, varscan2
- SMG9 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.029); catalogued as COSV54213521; called by muse, mutect2, varscan2
- SMURF1 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 155/236 reads (66%) | catalogued as COSV63155777; called by muse, mutect2, varscan2
- SOX8 | c.965C>G p.P322R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.277); catalogued as COSV53508743; called by muse, mutect2
- SPEM2 | c.336C>A p.F112L | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60366115; called by muse, mutect2, varscan2
- SRSF5 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV67936411; called by muse, mutect2, varscan2
- STAT5A | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1397391541, COSV61805738; called by muse, mutect2, varscan2
- STIM1 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV56151699; called by muse, mutect2, varscan2
- STIP1 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390256269, COSV54177062; called by muse, mutect2, varscan2
- STXBP5L | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56500582; called by muse, mutect2
- SUGP2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as COSV58255237; called by muse, varscan2
- TAB1 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs368517909; called by muse, mutect2, varscan2
- TAF4 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.809); catalogued as rs1436253281, COSV53334597; called by muse, mutect2, varscan2
- TENM3 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV69299659; called by muse, mutect2, varscan2
- TINAG | c.818T>C p.L273S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52505691; called by muse, mutect2, varscan2
- TMEM132B | c.289A>T p.I97F | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV54745158; called by muse, mutect2, varscan2
- TOP2A | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as COSV70732067; called by muse, mutect2, varscan2
- TRAPPC11 | c.2873G>A p.S958N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV58214614; called by muse, mutect2, varscan2
- TRAV25 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1219742521; called by muse, mutect2, varscan2
- TTN | c.28654G>A p.E9552K (on ENST00000591111; = p.E8625K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | PolyPhen probably damaging (0.994); catalogued as COSV59895218; called by muse, mutect2, varscan2
- TUBGCP6 | c.3890C>T p.P1297L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.044); catalogued as COSV50536785; called by muse, mutect2
- USF3 | c.5158C>T p.R1720C | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs377048228, COSV57069936, COSV57074695; called by muse, mutect2, varscan2
- VPS13D | c.11905C>T p.L3969F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as COSV99169828; called by mutect2, varscan2
- VWCE | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.841); catalogued as COSV57110997; called by muse, mutect2, varscan2
- YEATS2 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59361584; called by muse, mutect2, varscan2
- ZDHHC17 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.031); catalogued as COSV100602330; called by muse, mutect2
- ZFHX3 | c.11051A>T p.D3684V | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1484431562, COSV51709002; called by muse, mutect2, varscan2
- ZFYVE9 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55090265; called by muse, mutect2, varscan2
- ZNF518B | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs774467173, COSV58721376; called by muse, mutect2, varscan2
- ZNF560 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.804); catalogued as rs74178149, COSV56865396; called by muse, mutect2, varscan2
- ZNF564 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as rs757891327, COSV59434218; called by muse, mutect2, varscan2
- ZNF75A | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV73039564; called by muse, mutect2, varscan2
- CDKN2A | c.304dup p.A102Gfs*18 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- CYP2C19 | c.894del p.T299Qfs*8 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | called by mutect2, pindel, varscan2
- MTR | c.3659_3661del p.F1220del | In Frame Del (DEL) | VAF 13/137 reads (9%) | called by mutect2, pindel
- PRAMEF17 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2
- ACSBG2 | c.1236G>A p.L412= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV53122979; called by muse, mutect2, varscan2
- ACTRT1 | c.168C>T p.F56= | Silent (SNP) | VAF 31/198 reads (16%) | catalogued as rs141145093, COSV64418938; called by muse, mutect2, varscan2
- AMER1 | c.2511C>T p.S837= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV57655116; called by muse, mutect2
- ASPRV1 | c.40C>T p.L14= | Silent (SNP) | VAF 48/212 reads (23%) | catalogued as rs188178798, COSV57227425; called by muse, mutect2, varscan2
- ATG4D | c.1050C>T p.D350= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV57263632; called by muse, mutect2, varscan2
- ATXN7L2 | c.1725C>T p.S575= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as rs186977505; called by muse, mutect2, varscan2
- AWAT2 | c.447C>T p.F149= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV52142722, COSV52144805; called by muse, mutect2
- BIRC6 | c.3054C>T p.T1018= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV101429122; called by muse, mutect2, varscan2
- BMP10 | c.312C>T p.I104= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs1012401499, COSV54894075; called by muse, mutect2, varscan2
- BRWD3 | c.4528C>T p.L1510= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV64744037; called by muse, mutect2, varscan2
- BTBD11 | c.2583C>T p.L861= (on ENST00000280758 / NM_001018072.2; = p.L398= on NM_001017523.2) | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs200890069, COSV55017359; called by muse, mutect2
- CAMK1G | c.258C>T p.I86= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV50520264; called by muse, mutect2, varscan2
- CAPN13 | c.1645C>T p.L549= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs765506409, COSV54428491; called by muse, mutect2, varscan2
- CCDC160 | c.775C>T p.L259= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV66251330, COSV66251924; called by muse, mutect2, varscan2
- CCNB3 | c.1602G>A p.K534= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV52070039, COSV99329356; called by muse, mutect2, varscan2
- CCND1 | c.261C>G p.R87= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV57119357; called by muse, mutect2
- CDH12 | c.438C>T p.F146= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV66388805, COSV66392944; called by muse, mutect2, varscan2
- CDH22 | c.1332C>T p.I444= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV64836513; called by muse, mutect2, varscan2
- CDON | c.3861C>T p.T1287= (on ENST00000392693 / NM_001243597.2; = p.T1264= on NM_016952.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV54995223; called by muse, mutect2
- CFAP61 | c.3252G>A p.G1084= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs761444816, COSV55619619; called by muse, mutect2, varscan2
- CIITA | c.2097G>C p.P699= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV100162518, COSV60854149; called by muse, mutect2, varscan2
- CNTNAP2 | c.1389C>T p.F463= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs371242079; called by muse, mutect2, varscan2
- COL5A1 | c.1293G>T p.G431= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs373460629, CD129004, COSV65675834; ClinVar: benign; called by muse, mutect2, varscan2
- CYP2C9 | c.1140C>T p.L380= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53246578; called by muse, mutect2, varscan2
- D2HGDH | c.744C>T p.G248= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV58319125; called by muse, mutect2, varscan2
- DERL1 | c.78C>T p.P26= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV52364052; called by muse, mutect2, varscan2
- DNMT1 | c.3318T>C p.P1106= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as rs748574658, COSV61576612; called by muse, mutect2, varscan2
- DROSHA | c.396C>T p.V132= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV60772656; called by muse, mutect2, varscan2
- DSCAM | c.3657C>T p.I1219= | Silent (SNP) | VAF 47/187 reads (25%) | catalogued as COSV68021148; called by muse, mutect2, varscan2
- DYTN | c.1071G>A p.R357= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV71751577; called by muse, mutect2, varscan2
- ERBB4 | c.696A>G p.R232= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV53503237; called by muse, mutect2
- ERICH3 | c.1230G>A p.P410= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs375773806; called by muse, mutect2, varscan2
- FAAH2 | c.978C>T p.L326= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV66505494; called by muse, mutect2, varscan2
- FAM47C | c.1053G>A p.V351= | Silent (SNP) | VAF 26/207 reads (13%) | catalogued as COSV63723777; called by muse, mutect2, varscan2
- FEZF1 | c.231C>T p.F77= | Silent (SNP) | VAF 63/107 reads (59%) | catalogued as COSV58658202; called by muse, mutect2, varscan2
- FGF13 | c.411C>T p.F137= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV59543049, COSV59546526; called by muse, mutect2, varscan2
- FUT9 | c.264C>T p.I88= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100133427, COSV56142443; called by muse, mutect2, varscan2
- GAB4 | c.288G>A p.L96= | Silent (SNP) | VAF 52/251 reads (21%) | catalogued as COSV68752997; called by muse, mutect2, varscan2
- GOLGB1 | c.822C>T p.V274= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs548255954, COSV61461890; called by muse, mutect2, varscan2
- GRIA2 | c.1803C>T p.S601= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as rs147207421, COSV52382752; called by muse, mutect2, varscan2
- GRID1 | c.189C>T p.S63= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs757847476, COSV100022049, COSV60014650; called by muse, mutect2, varscan2
- HECTD4 | c.4458C>T p.A1486= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV61177821; called by muse, mutect2, varscan2
- HIVEP3 | c.5040C>T p.S1680= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs748776038, COSV56009919; called by muse, mutect2, varscan2
- IDH1 | c.567T>C p.I189= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV61616772; called by muse, mutect2, varscan2
- IGSF1 | c.1896C>T p.I632= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as rs772551917, COSV63836157; called by muse, mutect2, varscan2
- ITGAL | c.780C>T p.I260= | Silent (SNP) | VAF 44/241 reads (18%) | catalogued as rs267604509, COSV63320087; called by muse, mutect2, varscan2
- KCNH3 | c.1779A>G p.A593= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV57789672; called by muse, mutect2
- KIAA1210 | c.4890C>T p.F1630= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV68175526; called by muse, mutect2, varscan2
- KRT35 | c.291G>A p.E97= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as COSV55842298; called by muse, mutect2, varscan2
- LAMP3 | c.990G>A p.Q330= | Silent (SNP) | VAF 108/388 reads (28%) | catalogued as COSV55613571, COSV55615002; called by muse, mutect2, varscan2
- LCNL1 | c.285G>A p.R95= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV56399407; called by muse, mutect2
- LEXM | c.537G>A p.L179= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV64022073; called by muse, mutect2, varscan2
- LILRA2 | c.24G>A p.L8= | Silent (SNP) | VAF 21/206 reads (10%) | catalogued as COSV52188164, COSV52191564; called by muse, mutect2, varscan2
- M6PR | c.465C>T p.N155= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV50002570; called by muse, mutect2, varscan2
- MAEL | c.708C>T p.I236= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV63112284; called by muse, mutect2, varscan2
- MED12L | c.1020C>A p.G340= | Silent (SNP) | VAF 30/196 reads (15%) | catalogued as COSV56368838; called by muse, mutect2, varscan2
- MORC2 | c.1488C>T p.T496= (on ENST00000397641 / NM_001303256.3; = p.T434= on NM_014941.3) | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV53196354; called by muse, mutect2, varscan2
- NBEAL2 | c.3747C>T p.S1249= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52754288; called by mutect2, varscan2
- NIBAN2 | c.1287C>T p.F429= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV64823649, COSV64824539; called by muse, mutect2, varscan2
- NLRP3 | c.2076G>A p.E692= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1339015167, COSV60220219; called by muse, mutect2
- NOVA2 | c.1173C>T p.A391= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs1346607567, COSV54355978; called by muse, mutect2, varscan2
- NPM1 | c.828C>T p.F276= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV51545487; called by muse, mutect2, varscan2
- NXF3 | c.318G>A p.P106= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as rs768696726, COSV67702665; called by muse, mutect2, varscan2
- OR10AG1 | c.174C>T p.S58= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as rs374340251, COSV56631523; called by muse, mutect2
- OR10R2 | c.246C>T p.F82= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV63768476; called by muse, mutect2, varscan2
- OR11L1 | c.93C>T p.F31= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs753984060, COSV100869392, COSV63313648; called by muse, mutect2, varscan2
- OR4L1 | c.627C>T p.T209= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV100235866, COSV59848953; called by muse, mutect2, varscan2
- OR8J3 | c.72G>A p.Q24= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV56879438; called by muse, mutect2, varscan2
- PAK5 | c.1932C>T p.F644= | Silent (SNP) | VAF 21/129 reads (16%) | catalogued as COSV62021442; called by muse, mutect2, varscan2
- PCDHA3 | c.2367G>A p.Q789= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs1239467423, COSV63538976; called by muse, mutect2, varscan2
- PCDHA9 | c.2022G>A p.Q674= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV65323572; called by muse, mutect2, varscan2
- PCDHAC1 | c.2703C>T p.F901= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs868991363, COSV53837582; called by muse, mutect2, varscan2
- PCLO | c.3093G>A p.K1031= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as COSV61616727; called by muse, mutect2, varscan2
- PDE1C | c.1290C>T p.F430= | Silent (SNP) | VAF 78/139 reads (56%) | catalogued as COSV58503751; called by muse, mutect2, varscan2
- PIGT | c.792C>T p.F264= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54125133; called by muse, mutect2, varscan2
- PTPRD | c.3966G>A p.R1322= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs777253380, COSV61929130; called by muse, mutect2, varscan2
- RELN | c.1092C>T p.L364= | Silent (SNP) | VAF 70/117 reads (60%) | catalogued as rs142192165; ClinVar: likely benign; called by muse, mutect2, varscan2
- RIMBP2 | c.2646C>T p.I882= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs1181152747, COSV55464879; called by muse, mutect2, varscan2
- SALL1 | c.2790C>T p.S930= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV51753400; called by muse, mutect2, varscan2
- SERPINA11 | c.846G>A p.G282= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV58241166; called by muse, mutect2, varscan2
- SERPINB7 | c.636G>A p.R212= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV60532664; called by muse, mutect2, varscan2
- SH3BGR | c.90C>T p.P30= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as rs976526345, COSV61321725; called by muse, mutect2, varscan2
- SHROOM3 | c.1665C>T p.S555= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as COSV56023488; called by muse, mutect2, varscan2
- SLAMF9 | c.504C>T p.S168= | Silent (SNP) | VAF 43/157 reads (27%) | catalogued as rs373199961; called by muse, mutect2, varscan2
- SLC33A1 | c.768T>A p.T256= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100848352; called by muse, mutect2, varscan2
- SLC6A1 | c.1764G>A p.Q588= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV55113283; called by muse, mutect2, varscan2
- SMC2 | c.2914T>C p.L972= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV53955095; called by muse, mutect2, varscan2
- SNED1 | c.3102C>T p.T1034= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1450429801, COSV60019321; called by muse, mutect2, varscan2
- SPANXN2 | c.174G>A p.R58= | Silent (SNP) | VAF 70/197 reads (36%) | catalogued as COSV65127744, COSV65128399; called by muse, mutect2, varscan2
- SPATA31D1 | c.657C>T p.D219= | Silent (SNP) | VAF 24/244 reads (10%) | catalogued as COSV61192860; called by muse, mutect2, varscan2
- SPATA4 | c.537T>C p.V179= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV54588828; called by muse, mutect2, varscan2
- SPIC | c.256C>T p.L86= | Silent (SNP) | VAF 39/168 reads (23%) | catalogued as rs778706697, COSV54690324, COSV54690664, COSV54691988; called by muse, mutect2, varscan2
- SSTR1 | c.633C>T p.L211= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV57454970; called by muse, mutect2, varscan2
- TLN2 | c.5856C>T p.I1952= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs749661984, COSV60885431, COSV60886860; called by muse, mutect2, varscan2
- TMEM63B | c.2028C>T p.I676= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV52477111; called by muse, mutect2, varscan2
- TNRC18 | c.8343C>T p.F2781= | Silent (SNP) | VAF 91/140 reads (65%) | catalogued as COSV60306249; called by muse, mutect2, varscan2
- TTN | c.6084G>A p.E2028= (on ENST00000591111; = p.E1982= on NM_003319.4) | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV59895230; called by muse, mutect2, varscan2
- UBN1 | c.3243C>T p.S1081= | Silent (SNP) | VAF 68/287 reads (24%) | catalogued as COSV52165763; called by muse, mutect2, varscan2
- VPS16 | c.1215C>T p.F405= | Silent (SNP) | VAF 49/256 reads (19%) | catalogued as rs201606948, COSV66792137; called by muse, mutect2, varscan2
- YLPM1 | c.4095C>T p.F1365= | Silent (SNP) | VAF 48/168 reads (29%) | catalogued as COSV53106345; called by muse, mutect2, varscan2
- ZC3H7B | c.792G>A p.E264= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs1274713023, COSV60960545; called by muse, mutect2, varscan2
- ZDHHC17 | c.66G>A p.A22= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100602329; called by muse, mutect2
- ZNF157 | c.87C>T p.F29= | Silent (SNP) | VAF 35/179 reads (20%) | catalogued as rs758927576, COSV100998458, COSV65658436; called by muse, mutect2, varscan2
- ZNF667 | c.1710T>A p.L570= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV52631302; called by muse, mutect2, varscan2
- ZSCAN4 | c.312G>A p.V104= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV58998776; called by muse, mutect2, varscan2
- ASIC2 | c.556-179424G>A | Intron (SNP) | VAF 25/57 reads (44%) | catalogued as COSV56755951; called by muse, mutect2, varscan2
- ELMOD3 | c.943+171C>T | Intron (SNP) | VAF 26/142 reads (18%) | catalogued as COSV55706470; called by muse, mutect2, varscan2
- OR3A4P | n.911C>T | RNA (SNP) | VAF 76/151 reads (50%) | called by muse, mutect2, varscan2
- UBTFL2 | n.66G>A | RNA (SNP) | VAF 18/50 reads (36%) | called by mutect2, varscan2
